Gene-level copy-number profile of tumor specimen TCGA-ZF-A9RD-01A from TCGA case TCGA-ZF-A9RD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 75.3 years (27,496 days).
Specimen TCGA-ZF-A9RD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.5acd9d4b-e5ea-4593-9993-5ba42f60daea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-A9RD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b9dd702b-7e69-43fa-8088-a467b5211207

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 2: 11,469; copy number 3: 23,722; copy number 4: 18,289; copy number 5: 4,730; copy number 6: 501; copy number 7: 504; copy number 8: 29; copy number 10: 116; copy number 11: 125; copy number 12: 154; copy number 14: 82; copy number 18: 21; copy number 19: 22; copy number 21: 16; copy number 23: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-A9RD-01A-11D-A42D-01): tumor purity 0.38, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:29,048,620–29,650,440, 5 genes: RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,101 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:34,889,255–38,154,624, 90 genes, copy number 7–12 (within-gene range 3–12) (broad region; genes not listed).
- chr9:34,665,607–34,922,921, 10 genes, copy number 12 (within-gene range 3–12): AL162231.2, CCL19, AL162231.5, CCL21, FAM205A, AL589645.1, FAM205BP, FAM205C, GLULP4, YWHAZP6.
- chr9:92,210,207–95,426,796, 85 genes, copy number 8–12 (within-gene range 3–12) (broad region; genes not listed).
- chr9:105,656,369–109,119,947, 51 genes, copy number 12–21 (within-gene range 3–21): AL158070.2, TAL2, TMEM38B, AL592437.1, DEPDC1P2, SLC25A6P5, LINC01505, AL732323.1, AL451140.1, MIR8081, AL512649.2, RN7SKP77, AL512649.1, RNA5SP292, ZNF462, AL807761.4, AL512593.1, AL807761.1, AL807761.2, AL807761.3, AL445487.1, RAD23B, LINC01509, AL359552.1, HMGN2P32, RNU6-492P, KLF4, AL389915.1, PPIAP88, RNU6-996P, RNU6-1064P, RN7SL659P, RPL36AP6, AL162389.1, RNA5SP293, RPS15AP27, AC068050.1, CHCHD4P2, AL353742.1, AL669983.1, AL358779.1, RPL36AP35, AL359692.1, ACTL7B, ACTL7A, ELP1, ABITRAM, CTNNAL1, TMEM245, Y_RNA, MIR32.
- chr9:109,324,685–109,498,313, 2 genes, copy number 11 (within-gene range 3–11): Y_RNA, PTPN3.
- chr9:110,873,263–111,284,836, 5 genes, copy number 12 (within-gene range 3–12): LPAR1, RNU6-432P, Y_RNA, RNY4P18, AL162414.1.
- chr9:112,362,714–112,487,204, 3 genes, copy number 11 (within-gene range 3–11): AL359073.1, HSDL2, C9orf147.
- chr9:131,009,174–137,578,925, 251 genes, copy number 7–19 (within-gene range 3–19) (broad region; genes not listed).
- chr11:32,387,775–46,594,125, 214 genes, copy number 7–23 (within-gene range 4–23) (broad region; genes not listed).
- chr11:65,170,154–69,162,440, 226 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr12:5,432,108–7,800,467, 110 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr22:20,198,729–21,070,097, 54 genes, copy number 14: AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
